CCDI case PBCAEH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f1819f35-6547-4e84-b933-52755d4da5aa

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 0.3 years (115 days).

Biospecimens (2 samples)
- Sample 0DM4XA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM4XO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
